Somatic mutation profile of tumor specimen TCGA-DW-7838-01A (aliquot TCGA-DW-7838-01A-11D-2136-08) from TCGA case TCGA-DW-7838, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 66.4 years (24,247 days).
Specimen TCGA-DW-7838-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96f4776a-f43e-42f4-b18f-c839765bc350.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DW-7838-10A (Blood Derived Normal), aliquot TCGA-DW-7838-10A-01D-2136-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9178ea3a-8200-4173-96f0-46dd642cb8f8

The open-access MAF lists 88 somatic variants for this specimen: 66 protein-altering or splice-affecting, 22 silent.
By variant classification: Missense Mutation 55, Silent 22, Frame Shift Del 5, In Frame Del 2, Splice Site 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRF5 | c.157G>T p.V53F | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV51931147; called by muse, mutect2, varscan2
- AKR1C3 | c.260C>G p.S87C | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV65910171; called by muse, mutect2, varscan2
- BBX | c.1122G>C p.E374D | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV57881013; called by muse, mutect2, varscan2
- BIRC5 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as COSV56956077; called by muse, mutect2, varscan2
- BRSK2 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV57541409; called by muse, mutect2, varscan2
- BTAF1 | c.4545A>T p.K1515N | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56431150; called by muse, mutect2, varscan2
- C3orf18 | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs559763162, COSV51750082; called by muse, mutect2, varscan2
- CD177 | c.317A>G p.Q106R | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs761934579, COSV65120996; called by muse, mutect2, varscan2
- CENPE | c.3635T>A p.F1212Y | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.322); catalogued as COSV54378007; called by muse, mutect2, varscan2
- CEP192 | c.5281G>T p.D1761Y | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58061429; called by muse, mutect2, varscan2
- CLMN | c.1342G>A p.G448R | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.144); catalogued as COSV54180186; called by muse, mutect2, varscan2
- COL6A3 | c.563T>C p.I188T | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV55083405; called by muse, mutect2, varscan2
- CYP3A43 | c.820C>A p.Q274K | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs1301705611, COSV55935433; called by muse, mutect2, varscan2
- DMP1 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.593); catalogued as COSV56819061; called by muse, mutect2
- DPY19L3 | c.692T>G p.L231R | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60475314; called by muse, mutect2, varscan2
- EIF4B | c.1393C>T p.P465S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.207); catalogued as COSV50401892, COSV50402170; called by muse, mutect2, varscan2
- FBXO3 | c.1037C>A p.P346H | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55765464; called by muse, mutect2, varscan2
- FCAR | c.830T>G p.L277W | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV62028887; called by muse, mutect2, varscan2
- FCAR | c.831G>T p.L277F | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.042); catalogued as COSV62028389, COSV62028894; called by muse, mutect2, varscan2
- FIGN | c.1827T>A p.F609L | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (1); PolyPhen possibly damaging (0.628); catalogued as COSV60764343; called by muse, mutect2, varscan2
- FLAD1 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.124); catalogued as COSV52696160; called by muse, mutect2, varscan2
- FUT2 | c.344A>C p.H115P | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.894); catalogued as COSV67179074; called by muse, mutect2
- HSD17B4 | c.742C>T p.L248F (on ENST00000414835 / NM_001199291.3; = p.L223F on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/165 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); catalogued as COSV56334312; called by muse, mutect2, varscan2
- IL15RA | c.217A>G p.T73A | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV66092426; called by muse, mutect2, varscan2
- KIAA0825 | c.442T>G p.S148A | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56949505; called by muse, mutect2, varscan2
- KIF2C | c.137C>A p.A46E | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV64766653; called by muse, mutect2, varscan2
- KRT37 | c.1078G>C p.A360P | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as COSV56657329; called by muse, mutect2, varscan2
- MED13 | c.6408G>C p.Q2136H | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV67262516; called by muse, mutect2, varscan2
- OR1N2 | c.794del p.P265Lfs*19 | Frame Shift Del (DEL) | VAF 19/137 reads (14%) | catalogued as COSV65460309, COSV65460395; called by mutect2, pindel, varscan2
- PAK3 | c.163G>A p.G55R | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.194); catalogued as COSV53271805; called by mutect2, varscan2
- PKN3 | c.1402C>A p.P468T | Missense Mutation (SNP) | VAF 40/223 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0.343); catalogued as COSV52575560; called by muse, mutect2, varscan2
- POLR1A | c.2380G>A p.G794S | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55690563; called by muse, mutect2, varscan2
- PSD | c.353C>G p.P118R | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as COSV50042858; called by muse, mutect2, varscan2
- RELL1 | c.236A>T p.H79L | Missense Mutation (SNP) | VAF 26/239 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58450756; called by muse, mutect2, varscan2
- RFX6 | c.2458C>A p.Q820K | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.772); catalogued as COSV60584011; called by muse, mutect2, varscan2
- RIPOR1 | c.2402T>A p.L801Q (on ENST00000379312 / NM_001193522.2; = p.L797Q on NM_024519.4) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV50218748; called by muse, mutect2, varscan2
- RNF157 | c.486G>T p.Q162H | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53942661; called by muse, mutect2, varscan2
- SERINC2 | c.367G>A p.D123N (on ENST00000373709 / NM_178865.5; = p.D127N on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV65489688; called by muse, mutect2
- SIGLEC12 | c.281A>T p.H94L | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as COSV52460184; called by muse, mutect2, varscan2
- SLC31A1 | c.42dup p.N15Qfs*38 | Frame Shift Ins (INS) | VAF 15/110 reads (14%) | catalogued as rs1477457884; called by mutect2, pindel, varscan2
- SPTBN5 | c.8356G>C p.A2786P | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58018118; called by muse, mutect2, varscan2
- SVOPL | c.1397C>T p.S466L (on ENST00000419765; = p.S314L on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV55989290; called by muse, mutect2, varscan2
- TRIM63 | c.578A>T p.D193V | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV65327998; called by muse, mutect2, varscan2
- TSNARE1 | c.1210G>C p.E404Q | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.353); catalogued as COSV56172476; called by muse, mutect2, varscan2
- TSTD2 | c.919C>A p.L307I | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.206); catalogued as COSV52245726; called by muse, mutect2, varscan2
- TTN | c.2437A>T p.S813C (on ENST00000591111; = p.S767C on NM_003319.4) | Missense Mutation (SNP) | VAF 15/82 reads (18%) | PolyPhen possibly damaging (0.794); catalogued as COSV59943196; called by muse, mutect2, varscan2
- USP5 | c.1109C>T p.T370I | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.944); catalogued as COSV57536025; called by muse, mutect2, varscan2
- VDAC2 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.042); catalogued as COSV53685373; called by muse, mutect2, varscan2
- ZAN | c.4190C>T p.T1397I | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs1310753502, COSV61806628; called by muse, mutect2, varscan2
- ZER1 | c.1276T>C p.Y426H | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.125); catalogued as COSV52564754; called by mutect2, varscan2
- ZNF28 | c.1297C>G p.H433D | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV60422047, COSV60422421; called by muse, mutect2, varscan2
- ZNF430 | c.1666C>G p.L556V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as COSV55108515; called by muse, mutect2, varscan2
- ZNF608 | c.4049C>T p.P1350L | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60436148; called by muse, mutect2, varscan2
- ZNF761 | c.246T>G p.N82K | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV61887854; called by muse, mutect2
- ZNF777 | c.596T>A p.L199Q | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV56096670; called by muse, mutect2, varscan2
- ZZEF1 | c.8086G>T p.G2696* | Nonsense Mutation (SNP) | VAF 37/151 reads (25%) | catalogued as COSV67556384; called by muse, mutect2, varscan2
- ADCY5 | c.1001del p.F334Sfs*43 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.4567_4572del p.K1523_S1524del | In Frame Del (DEL) | VAF 38/135 reads (28%) | called by mutect2, pindel, varscan2
- C16orf92 | c.284_289+13del p.X95_splice | Splice Site (DEL) | VAF 19/77 reads (25%) | called by mutect2, pindel, varscan2
- CGRRF1 | c.940G>C p.E314Q | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); called by muse, mutect2
- DMTF1 | c.549del p.I184Sfs*16 | Frame Shift Del (DEL) | VAF 10/53 reads (19%) | called by mutect2, pindel, varscan2
- MFSD10 | c.304C>G p.L102V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2
- MMRN2 | c.401-1_402del p.X134_splice | Splice Site (DEL) | VAF 8/61 reads (13%) | called by mutect2, pindel, varscan2
- WDR47 | c.563del p.K188Rfs*11 | Frame Shift Del (DEL) | VAF 49/331 reads (15%) | called by mutect2, pindel, varscan2
- WIPF2 | c.369_374del p.R124_P125del | In Frame Del (DEL) | VAF 30/139 reads (22%) | called by pindel, varscan2
- ZNF227 | c.917del p.F306Sfs*146 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, varscan2
- AKR1B15 | c.684C>T p.C228= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as rs267601304, COSV71151288; called by muse, mutect2, varscan2
- ANKRD35 | c.1353C>T p.T451= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as COSV62909862; called by muse, mutect2, varscan2
- APCDD1 | c.630G>A p.Q210= | Silent (SNP) | VAF 36/202 reads (18%) | catalogued as COSV100790030, COSV62372229; called by muse, mutect2, varscan2
- ATF7IP | c.2553C>T p.P851= | Silent (SNP) | VAF 25/177 reads (14%) | catalogued as rs1211992416, COSV53767873; called by muse, mutect2, varscan2
- EHHADH | c.747C>T p.I249= | Silent (SNP) | VAF 79/258 reads (31%) | catalogued as COSV51628630; called by muse, mutect2, varscan2
- HEBP2 | c.318C>A p.T106= | Silent (SNP) | VAF 34/184 reads (18%) | catalogued as rs752232541, COSV62928152; called by muse, mutect2, varscan2
- HSPA5 | c.762T>C p.G254= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs747075001, COSV100190139; called by muse, mutect2, varscan2
- JAKMIP1 | c.1362G>A p.L454= | Silent (SNP) | VAF 6/91 reads (7%) | catalogued as COSV51525037; called by muse, mutect2
- LAMA3 | c.4803G>T p.V1601= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as COSV52531818; called by muse, mutect2, varscan2
- LOXL3 | c.1899C>T p.H633= | Silent (SNP) | VAF 18/112 reads (16%) | catalogued as COSV51206501; called by muse, mutect2, varscan2
- POU6F2 | c.942C>T p.S314= | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as COSV68869657; called by muse, mutect2, varscan2
- RNPEPL1 | c.1716C>T p.L572= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as COSV54372158; called by muse, mutect2, varscan2
- SALL1 | c.3282T>C p.H1094= | Silent (SNP) | VAF 17/111 reads (15%) | catalogued as COSV51754861; called by muse, mutect2, varscan2
- SCAP | c.3102G>A p.L1034= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV55543366, COSV99650498; called by muse, mutect2, varscan2
- SLC38A7 | c.204G>A p.G68= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV54702628; called by muse, mutect2, varscan2
- SYNE2 | c.16653G>A p.L5551= | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as COSV59943643; called by muse, mutect2, varscan2
- TUBA3D | c.315G>A p.R105= | Silent (SNP) | VAF 38/234 reads (16%) | catalogued as COSV58311168; called by muse, mutect2, varscan2
- WIPF2 | c.378A>G p.P126= | Silent (SNP) | VAF 34/145 reads (23%) | catalogued as rs139121244; called by muse, varscan2
- ZMIZ2 | c.2298C>G p.P766= | Silent (SNP) | VAF 19/130 reads (15%) | catalogued as COSV54806622; called by muse, mutect2, varscan2
- ZNF473 | c.2499G>T p.L833= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as COSV54522383; called by muse, mutect2, varscan2
- ZNF519 | c.864A>G p.G288= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV73913230; called by muse, mutect2, varscan2
- ZNF521 | c.2253C>G p.V751= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV64123869; called by muse, mutect2, varscan2
